Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5460, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5460-01A (Primary Tumor).

[page 1 of 3]
Accession Number: [REDACTED] Report Status: Amend/Addenda
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

CASE: [REDACTED]
PATIENT: [REDACTED]

***** Addended Report *****

TCGA-CZ-5460

PATHOLOGIC DIAGNOSIS:

SPECIMEN LABELED "RIGHT KIDNEY":

RENAL CELL CARCINOMA, clear-cell type, (2.4 cm), Fuhrman Grade II/IV
(focally III/IV), involving the mid and inferior pole.

Tumor embolus is present at the renal vein margin.

Tumor is confined to kidney (except for tumor emboli).

Extensive tumor emboli are present in vasculature.

Ureteral and arterial margins are negative for tumor.

Gerota's fascial and soft-tissue margins are negative for tumor.

AJCC Classification (6th Edition): pT3b Nx Mx.

The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

CLINICAL DATA:

History: None given.

Operation: Right radical nephrectomy.

Operative Findings: None given.

Clinical Diagnosis: Renal cell carcinoma.

TISSUE SUBMITTED:

A/1. Right kidney.

GROSS DESCRIPTION:

The specimen, Part A, is received fresh, labeled with the patient's name, unit number, and "#1. Right kidney", consists of a 483-gram radical nephrectomy specimen (overall dimensions 17.0 x 7.2 x 5.0 cm) consisting of kidney (10.2 x 6.3 x 4.8 cm) and attached yellow/tan lobulated perinephric adipose tissue (up to 3.5 cm in thickness). Extending from the renal hilum is a segment of ureter (6.2 cm length x 0.3 cm in diameter), a segment of renal artery (1.6 cm length x 0.4 cm in diameter), and a segment of renal vein (0.5 cm length x 1.0 cm in diameter).

In the mid pole, there is a well-circumscribed golden yellow focally hemorrhagic mass (2.4 x 2.4 x 1.0 cm), which grossly appears to arise from the renal parenchyma and focally distorts but does not appear to invade into the renal sinus. Upon sectioning, the mass is confined to the renal parenchyma, does not grossly appear to involve the renal capsule, and comes within 2.4 cm of the perinephric soft tissue resection margin.

Within the renal vein, there is a loosely adherent friable hemorrhagic red/brown to yellow/brown necrotic tissue (probable tumor thrombus) contiguous with the aforementioned mass, which grossly appears to come within 0.2 cm of the renal vein margin (previously sampled en face in the frozen section room). The aforementioned comes within 2.4 cm of the renal artery margin and 5.5 cm of the ureteral margin.

A 0.9 cm inferior to the aforementioned mass, in the inferior pole of the kidney, there is a well-circumscribed yellow/tan friable nodule (? satellite lesion, 0.8 x 0.6 x 0.6 cm).

The pelvic calyceal system exhibits smooth, glistening tan mucosa. The corticomedullary junction is distinct. No lymph nodes are identified within the perinephric adipose tissue.

A representative section of the specimen was photographed.

[page 2 of 3]
[REDACTED]

which 7 (3.5 %) are globally sclerosed. The remaining glomeruli show mild diffuse mesangial expansion; overt nodular glomerulosclerosis is not noted at this time. There are no discernible craters or double contours of the glomerular basement membranes. Rare distal tubules contain PAS-positive hyaline casts. Less than 5% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries and arterioles exhibit a mild to focally moderate degree of sclerosis; some small arteries reveal significant narrowing of the lumen by accumulation of connective tissue in the subintima. Arterioles show early focal hyaline degeneration.

[REDACTED]

[page 3 of 3]
[REDACTED]

Accession Number: [REDACTED]

Report Status: Final

Type: Cytogenetics

CASE: [REDACTED]

PATIENT: [REDACTED]

Cytogen: [REDACTED]

KARYOTYPE:

45,XY,del(3)(p11),del(6)(q12q25),der(9)t(7;9)(q1?1;q3?4),-21[cp4]/ 80,idem
x2[6]

METAPHASES COUNTED: 10

ANALYZED: 6

SCORED: 4

BANDING: GTG

INTERPRETATION:

All metaphases contained clonal aberrations including loss of the short arm of chromosome 3, which is a characteristic finding in renal cell carcinoma, clear cell type.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

RCC

[REDACTED]

Source: NCI Genomic Data Commons file 70236462-a15a-42e7-84e7-92ac197e6dbb (TCGA-CZ-5460.15106EEA-87C3-4349-8613-2D750D6D342D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).